Somatic mutation profile of tumor specimen TCGA-28-5216-01A (aliquot TCGA-28-5216-01A-01D-1486-08) from TCGA case TCGA-28-5216, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 52.7 years (19,239 days).
Specimen TCGA-28-5216-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e905276-6586-4913-bcfc-4becd8cac17f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-5216-10A (Blood Derived Normal), aliquot TCGA-28-5216-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca16ba46-fd07-4438-991c-7dd08efec0e7

The open-access MAF lists 49 somatic variants for this specimen: 37 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 11, Splice Site 2, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.746G>T p.R249M | Missense Mutation (SNP) | VAF 53/69 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs587782329, COSV52666526, COSV52668050, COSV52697169, COSV52713804; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CEACAM20 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs756391229, COSV57602058; called by muse, mutect2, varscan2
- CEP44 | c.508-2A>G p.X170_splice | Splice Site (SNP) | VAF 65/154 reads (42%) | catalogued as COSV56659765; called by muse, mutect2, varscan2
- CFAP300 | c.675+2T>C p.X225_splice | Splice Site (SNP) | VAF 28/119 reads (24%) | catalogued as COSV101462452; called by muse, mutect2, varscan2
- CHD3 | c.5078G>A p.R1693Q (on ENST00000330494 / NM_001005273.3; = p.R1659Q on NM_005852.4) | Missense Mutation (SNP) | VAF 70/190 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.131); catalogued as rs1317429846, COSV57876606; called by muse, mutect2, varscan2
- DNAH7 | c.5257G>C p.E1753Q | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56763793, COSV56770131; called by muse, mutect2
- DSG3 | c.2000A>G p.H667R | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.084); catalogued as rs574305228, COSV57127254; called by muse, mutect2, varscan2
- GDPD5 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1405132857, COSV61126659; called by muse, mutect2, varscan2
- GPN1 | c.572C>T p.T191I | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.085); catalogued as COSV53115394; called by muse, mutect2
- HEATR5A | c.2849G>A p.S950N | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as rs569072683, COSV66342248; called by muse, mutect2, varscan2
- HRNR | c.3332A>T p.Q1111L | Missense Mutation (SNP) | VAF 124/1163 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV100913262; called by muse, varscan2
- KCNK9 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 107/226 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781672892, COSV57280188, COSV57280425; called by muse, mutect2, varscan2
- KIAA1109 | c.10666C>G p.L3556V | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52678424, COSV52682016; called by muse, mutect2, varscan2
- KIF7 | c.1903C>T p.R635W | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.63); catalogued as rs150543610; called by muse, mutect2
- MMP9 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 210/369 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as COSV63434188; called by muse, mutect2, varscan2
- MUC17 | c.13469C>T p.T4490M | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as rs534194993, COSV60292396; called by muse, mutect2, varscan2
- MYLIP | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.995); catalogued as COSV62766996; called by muse, mutect2, varscan2
- NUTM1 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as rs138533937; called by muse, mutect2
- OR51E1 | c.211G>C p.G71R | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); catalogued as COSV67810289; called by muse, mutect2, varscan2
- OR6B1 | c.209A>T p.E70V | Missense Mutation (SNP) | VAF 106/221 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68770291; called by muse, mutect2, varscan2
- P2RY2 | c.1081C>T p.R361W | Missense Mutation (SNP) | VAF 122/278 reads (44%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.165); catalogued as rs1443879556, COSV60775897; called by muse, mutect2
- PCDHA1 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 130/300 reads (43%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.052); catalogued as rs1446677911, COSV65374909; called by muse, mutect2, varscan2
- PCNX1 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 2/20 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1327618751, COSV53097101; called by muse, mutect2
- PSMD4 | c.395A>G p.K132R | Missense Mutation (SNP) | VAF 5/110 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV64393544; called by muse, mutect2
- PTEN | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 85/122 reads (70%) | SIFT tolerated (0.05); PolyPhen benign (0.1); catalogued as COSV64298579, COSV64311315; called by muse, mutect2, varscan2
- RFX1 | c.1667G>A p.G556E | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as COSV54330714; called by muse, mutect2, varscan2
- RUNX1T1 | c.239C>T p.T80M (on ENST00000265814 / NM_001198628.1; = p.T53M on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/88 reads (60%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as rs758568072, COSV56151071, COSV56153017; called by muse, mutect2, varscan2
- SETD2 | c.5321A>G p.H1774R | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57440982; called by muse, mutect2, varscan2
- SLMAP | c.1537G>T p.A513S (on ENST00000428312 / NM_001377924.1; = p.A575S on NM_007159.5) | Missense Mutation (SNP) | VAF 112/194 reads (58%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.087); catalogued as COSV55849187; called by muse, mutect2, varscan2
- SOX5 | c.211T>C p.S71P | Missense Mutation (SNP) | VAF 280/537 reads (52%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.315); catalogued as COSV58634402; called by muse, mutect2, varscan2
- TTN | c.38852T>G p.L12951R (on ENST00000591111; = p.L5527R on NM_003319.4) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | PolyPhen probably damaging (0.999); catalogued as COSV60139847; called by muse, mutect2, varscan2
- UMOD | c.1014T>A p.N338K | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.062); catalogued as COSV56776705; called by muse, mutect2, varscan2
- USP35 | c.1817G>A p.C606Y | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71573029; called by muse, mutect2, varscan2
- XCL1 | c.79T>G p.S27A | Missense Mutation (SNP) | VAF 88/209 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV63192357; called by muse, mutect2, varscan2
- ZDBF2 | c.1757A>G p.D586G | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as rs1314163387, COSV65627214; called by muse, mutect2, varscan2
- ZNF608 | c.296A>C p.K99T | Missense Mutation (SNP) | VAF 70/138 reads (51%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.647); catalogued as COSV60438775; called by muse, mutect2, varscan2
- FUT4 | c.942_945del p.N315Gfs*46 | Frame Shift Del (DEL) | VAF 18/66 reads (27%) | called by pindel, varscan2
- ABCA8 | c.1194T>A p.I398= | Silent (SNP) | VAF 90/108 reads (83%) | catalogued as COSV52204125; called by muse, mutect2, varscan2
- ARL1 | c.171G>A p.T57= | Silent (SNP) | VAF 38/125 reads (30%) | catalogued as rs375724509; called by muse, mutect2, varscan2
- CEP290 | c.2118T>C p.D706= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV58352929; called by muse, mutect2, varscan2
- CPAMD8 | c.4761C>T p.D1587= (on ENST00000651564; = p.D1540= on NM_015692.5) | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as rs748210595, COSV71596770; called by muse, mutect2, varscan2
- GPR132 | c.225C>T p.N75= | Silent (SNP) | VAF 76/89 reads (85%) | catalogued as rs371334440; called by muse, mutect2, varscan2
- MS4A14 | c.30A>T p.A10= | Silent (SNP) | VAF 42/77 reads (55%) | catalogued as COSV55730224; called by muse, mutect2, varscan2
- MYH2 | c.4668T>C p.S1556= | Silent (SNP) | VAF 206/250 reads (82%) | catalogued as COSV55440957; called by muse, mutect2, varscan2
- PLEC | c.12255G>A p.S4085= (on ENST00000322810 / NM_201380.4; = p.S3975= on NM_000445.5) | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs782025071, COSV100516634, COSV59650533; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SALL4 | c.588G>T p.R196= | Silent (SNP) | VAF 95/314 reads (30%) | catalogued as COSV53853414; called by muse, mutect2, varscan2
- SLC18A2 | c.780C>T p.L260= | Silent (SNP) | VAF 52/64 reads (81%) | catalogued as rs1172146522, COSV53691328, COSV53693565; called by muse, mutect2, varscan2
- ZFR2 | c.1341G>T p.A447= | Silent (SNP) | VAF 36/386 reads (9%) | catalogued as rs371065673, COSV53599890; called by muse, mutect2
- C7orf65 | n.258C>A | RNA (SNP) | VAF 43/95 reads (45%) | called by muse, mutect2, varscan2
